Surgical pathology report (de-identified scan), TCGA case TCGA-XK-AAIW, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-XK-AAIW-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

ICD O-3
Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9
7/23/25/14

Patient Name: [REDACTED]
Clinic Number: [REDACTED]
Date of Birth: (Age: Gender: M)
Requested By:

Accession #:
Procedure Date:
Received Date:
Account #:
Report Signed:

Final Diagnosis:

Procedure: Radical prostatectomy and bilateral pelvic dissection.

Histologic type: Prostatic adenocarcinoma.

Histologic grade:

Primary pattern: 5, Secondary pattern: 4, Tertiary pattern: Not applicable.

Total Gleason Score: 9 of 10.

Tumor quantitation and location: Tumor is identified in both lobes of the prostate for a total of 12 out of 16 sections of prostate and seminal vesicle being involved by carcinoma. The largest focus of carcinoma measures at least 2.2 cm, (measured, however, in a single slide with tumor extending to the edges of the section). Areas involved are identified in sections from the proximal urethral margin to the apices of prostate.

Extraprostatic extension: Present in left mid and right mid of the prostate, in the left base and the right base of the prostate, and around the left and right seminal vesicles.

Margins: Surgical margin involved by prostatic adenocarcinoma in the left apical area (17 mm involvement), in the left bladder neck margin (8 mm length of involvement of margin).

Lymph-vascular invasion: Present.

Perineural invasion: Present.

Seminal vesicle invasion: Present, bilateral.

Treatment effect on carcinoma: Not recognized.

Lymph nodes: Seven lymph nodes retrieved, all negative for malignancy (0/7).

Additional pathologic findings: None of additional relevance.

Ancillary studies: Not performed.

Pathologic staging: pT3b, pN0, pM not applicable.

Biorepository sample (if applicable): The sample obtained is completely involved by carcinoma (100% of nuclei are malignant).

Block(s) containing malignancy suitable for additional testing: A7 through A16.

Interpreted by:

Report electronically signed out by

Transcribed by:

Clinical Information:

[page 2 of 3]
Prostate carcinoma.

Specimen(s):

A: Prostate with bilateral lymph nodes

Gross Description:

Performed by *Pathologist's Assistant*

A1A2A3A4A5A6A7A8A9A10A11A12A13A14A15A16A17A18A19A20A21A22

A. Received fresh labeled [redacted] and "prostate and bilateral pelvic lymph nodes":

Procedure: Radical prostatectomy, pelvic lymph node dissection.

Prostate size: Weight: 102 grams; Dimensions: 6 x 5.5 x 5.5 cm; Seminal vesicles: 4.5 x 2.5 x 0.7 cm.

Gross notes: Grossly evident tumor: There is a diffuse solid gold pattern involving the posterior prostate from the apex to the base. It is poorly defined and cannot be adequately measured.

Symmetry: The left side is larger than the right side.

Gross nodular hyperplasia: Moderate to severe.

Gross capsular bulge/defect: None.

Inking: left-black, right-blue

Biorepository sample collected: Yes. See block key. Urology

Lymph nodes: Pelvic lymph node dissection is present 4 x 4 x 1 cm. Eleven lymph nodes are found ranging in size from 2.0 x 0.8 x 0.6 cm to 0.4 cm in diameter. The right side of the specimen is inked blue, the left side is inked black.

Block key for specimen : Representative sections are submitted in twenty-two cassettes labeled A1 through A22.

- 1) proximal urethral margin
- 2) distal urethral margin
- 3) left apical margin, perpendicular
- 4) right apical margin, perpendicular
- 5) left bladder neck margin, perpendicular
- 6) right bladder neck margin, perpendicular
- 7) left apical prostate
- 8) right apical prostate
- 9) left mid prostate
- 10) right mid prostate
- 11) left mid prostate
- 12) right mid prostate
- 13) left base of prostate
- 14) right base of prostate
- 15) left seminal vesicle
- 16) right seminal vesicle

Additional sections:

17) sample corresponding to research tissue

18-22) lymph nodes. A18-A20) one lymph node each. A21-A22) four lymph nodes.

*Per TSS dx discrepancy form,
TCGA tumor Gleason is 5+5.*

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by

They have not been cleared or approved by the U. S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Primary 5 Secondary 4 Total 9	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Primary 5 Secondary 5 Total 10	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	During path review it was determined Gleason score on path report is different than TCGA sample Gleason score determined by	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Date

Source: NCI Genomic Data Commons file a7a36a18-8197-4e2e-ba75-d33a6c433603 (TCGA-XK-AAIW.A6E4263E-CFAA-4704-B143-095BA0E8DABF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).